Somatic mutation profile of tumor specimen 0DRELG from CCDI case PBCEWM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.5 years (5,302 days).
Specimen 0DRELG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c06d90d6-ebe6-4b18-8e76-c2ba345bbca4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRELE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43a52b52-322b-4553-84bb-53dc67604245

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Intron 5, Nonsense Mutation 4, 3'UTR 2, 5'UTR 1, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM17 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 106/766 reads (14%) | catalogued as rs866715181; called by muse, varscan2
- ANO4 | c.2033G>C p.R678T (on ENST00000392977 / NM_001286615.2; = p.R643T on NM_178826.4) | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV54608899; called by muse, varscan2
- ATP10B | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752017849, COSV59166438; called by muse, varscan2
- CFAP94 | c.641A>G p.Y214C (on ENST00000320267 / NM_001352064.2; = p.Y220C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/571 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.118); catalogued as rs751471398; called by muse, varscan2
- CP | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1310224806; called by muse, varscan2
- ECI2 | c.469C>T p.R157W (on ENST00000380118 / NM_206836.3; = p.R127W on NM_006117.2) | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777148496; called by muse, varscan2
- EVPL | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 98/790 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs749502540; called by muse, varscan2
- FOXP3 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 258/474 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145368924, COSV66050838; called by muse, varscan2
- KAT5 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 191/469 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs747460009, COSV100384020; called by muse, varscan2
- KDM6A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 127/492 reads (26%) | catalogued as rs189751539, CM146948, COSV65037198; called by muse, varscan2
- NABP2 | c.-23-7C>T | Splice Region (SNP) | VAF 80/294 reads (27%) | catalogued as rs745737165; called by muse, varscan2
- OR6C6 | c.312A>C p.L104F | Missense Mutation (SNP) | VAF 67/494 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV64455613; called by muse, varscan2
- OR8S1 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 150/464 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs752425025; called by muse, varscan2
- PCDH17 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64974174; called by muse, varscan2
- PDE1B | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 88/665 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182942643, COSV54490897, COSV54491804; called by muse, varscan2
- RRAGD | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 134/690 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs370763603; called by muse, varscan2
- SFI1 | c.1901C>T p.A634V (on ENST00000400288 / NM_001007467.3; = p.A603V on NM_014775.4) | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs984128885; called by muse, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- TBC1D12 | c.1874G>C p.R625P | Missense Mutation (SNP) | VAF 207/613 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56553668, COSV56557387, COSV56558024; called by muse, varscan2
- TLR3 | c.1481A>T p.N494I | Missense Mutation (SNP) | VAF 104/586 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV57168184; called by muse, varscan2
- TNR | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 170/502 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778097851, COSV54906440; called by muse, varscan2
- ANKRD45 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 155/377 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- CCT8L2 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 50/431 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); called by muse, varscan2
- DNAH10 | c.4882A>G p.R1628G (on ENST00000409039; = p.R1567G on NM_207437.3) | Missense Mutation (SNP) | VAF 72/549 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DSC3 | c.273A>T p.K91N | Missense Mutation (SNP) | VAF 107/549 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, varscan2
- JAG1 | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 90/637 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, varscan2
- OR10AC1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 176/502 reads (35%) | SIFT deleterious, low confidence (0.03); called by muse, varscan2
- PGLYRP3 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, varscan2
- RSPH6A | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 50/439 reads (11%) | called by muse, varscan2
- SLC35F4 | c.1342C>A p.Q448K (on ENST00000339762 / NM_001352015.2; = p.Q412K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, varscan2
- VWC2 | c.810T>A p.C270* | Nonsense Mutation (SNP) | VAF 94/300 reads (31%) | called by muse, varscan2
- ZMYND8 | c.883G>T p.A295S (on ENST00000311275 / NM_001363741.2; = p.A315S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/756 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); called by muse, varscan2
- GET3 | c.33G>A p.E11= | Silent (SNP) | VAF 108/534 reads (20%) | catalogued as rs1485624213; called by muse, varscan2
- KNDC1 | c.438G>T p.L146= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, varscan2
- MUC16 | c.14355G>A p.K4785= | Silent (SNP) | VAF 101/867 reads (12%) | called by muse, varscan2
- OR4D6 | c.903G>T p.L301= | Silent (SNP) | VAF 78/418 reads (19%) | called by muse, varscan2
- OSM | c.687G>A p.R229= | Silent (SNP) | VAF 140/406 reads (34%) | called by muse, varscan2
- PITRM1 | c.1014C>T p.T338= | Silent (SNP) | VAF 76/601 reads (13%) | catalogued as rs759621495; called by muse, varscan2
- PPP1R2B | c.189T>C p.Y63= | Silent (SNP) | VAF 69/469 reads (15%) | catalogued as rs1420198479; called by muse, varscan2
- RNF139 | c.1389C>T p.Y463= | Silent (SNP) | VAF 248/1258 reads (20%) | catalogued as rs200926280; called by muse, varscan2
- AAK1 | c.*96C>G | 3'UTR (SNP) | VAF 66/215 reads (31%) | called by muse, varscan2
- ARFGAP1 | c.834+257G>T | Intron (SNP) | VAF 232/514 reads (45%) | catalogued as rs1392543323; called by muse, varscan2
- C2CD6 | c.1582-3661A>G | Intron (SNP) | VAF 82/728 reads (11%) | called by muse, varscan2
- COL4A2 | c.1340-216C>T | Intron (SNP) | VAF 179/1283 reads (14%) | called by muse, varscan2
- ETV5 | c.*15G>C | 3'UTR (SNP) | VAF 86/370 reads (23%) | called by muse, varscan2
- KANK3 | chr19:8322792 C>T | 3'Flank (SNP) | VAF 26/188 reads (14%) | catalogued as rs1555786389, COSV100035694; called by muse, varscan2
- PCDH11X | c.3033+22A>T | Intron (SNP) | VAF 34/174 reads (20%) | called by muse, varscan2
- PRKACB | c.765+1751G>A | Intron (SNP) | VAF 121/676 reads (18%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, varscan2
- SALL1 | chr16:51151292 C>G | 5'Flank (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
